Somatic mutation profile of tumor specimen MP2PRT-PAPUBE-TMP1-A (aliquot MP2PRT-PAPUBE-TMP1-A-1-0-D-A83A-36) from MP2PRT case MP2PRT-PAPUBE, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Primary diagnosis: Acute lymphoblastic leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.3 years (1,223 days).
Specimen MP2PRT-PAPUBE-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3083efd7-5114-414d-8d47-279ab86979cd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAPUBE-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAPUBE-NB1-A-1-0-D-A83A-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2f090213-1256-4a93-8406-df441d0dc023

The open-access MAF lists 5 somatic variants for this specimen: 4 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 4, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DNAH9 | c.12613C>T p.R4205W | Missense Mutation (SNP) | VAF 17/305 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.315); catalogued as rs767306011, COSV52335715; called by muse, mutect2
- PTPN21 | c.1679C>T p.T560M | Missense Mutation (SNP) | VAF 166/597 reads (28%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.98); catalogued as rs569738035, COSV60848408; called by muse, mutect2, varscan2
- THRAP3 | c.398G>A p.R133K | Missense Mutation (SNP) | VAF 22/438 reads (5%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.647); catalogued as rs1403822494; called by muse, mutect2
- ZNF727 | c.652C>A p.H218N | Missense Mutation (SNP) | VAF 33/307 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.8); called by muse, mutect2, varscan2
- MAGEL2 | c.2826C>T p.G942= | Silent (SNP) | VAF 172/406 reads (42%) | catalogued as rs373597907; called by muse, mutect2, varscan2
